Somatic mutation profile of tumor specimen TCGA-F4-6808-01A (aliquot TCGA-F4-6808-01A-11D-1835-10) from TCGA case TCGA-F4-6808, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 54.2 years (19,803 days).
Specimen TCGA-F4-6808-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44edec77-5a8f-4eb1-a048-a3caeebe73de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6808-10A (Blood Derived Normal), aliquot TCGA-F4-6808-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5e9de8a-70cc-41b5-bf3d-65dd3c88aedd

The open-access MAF lists 140 somatic variants for this specimen: 103 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 34, Nonsense Mutation 10, Intron 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs1211642532, CM994565, COSV57322919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.7327C>T p.R2443* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as rs121434220, CM960104, COSV53724743, COSV53745412; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.5356C>T p.R1786C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1555471394, COSV52135847; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL8 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs115824043, COSV64861249; called by muse, mutect2, varscan2
- ACVR1C | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV54648912; called by muse, mutect2, varscan2
- ADAMTS5 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs750142658, COSV53179020, COSV53186795; called by muse, mutect2, varscan2
- ADAMTS9 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as rs776836604, COSV55787594; called by muse, mutect2, varscan2
- ADH1A | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.366); catalogued as COSV52925883; called by muse, mutect2, varscan2
- AKT3 | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55623986, COSV99795114; called by muse, mutect2, varscan2
- ANK3 | c.9199G>A p.D3067N | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs568053112, COSV55048630; called by muse, mutect2, varscan2
- ARX | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445093587, COSV66875685; called by muse, mutect2, varscan2
- B3GALT4 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs765740368, COSV65851334; called by muse, mutect2, varscan2
- BABAM1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs766735279, COSV53105514; called by muse, mutect2, varscan2
- BIRC6 | c.13180G>T p.A4394S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as COSV70203976; called by muse, mutect2
- BMPR2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs937502048, CM1513958, COSV101001430; called by muse, mutect2, varscan2
- C8orf37 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54413423; called by muse, mutect2
- CACNA1H | c.4007C>T p.T1336M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370725735, COSV62000070; called by muse, mutect2
- CEP162 | c.972A>T p.K324N | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100002693; called by muse, mutect2
- CES1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62089376; called by muse, mutect2, varscan2
- CFAP251 | c.579A>T p.E193D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV56614267; called by muse, mutect2, varscan2
- CHD5 | c.2726C>A p.A909D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52422180; called by muse, mutect2, varscan2
- COL5A1 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs781485753, COSV65666385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs927215294, COSV55624141, COSV55643467; called by muse, mutect2, varscan2
- DNAH8 | c.12791G>C p.R4264T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100543818, COSV100544619; called by muse, mutect2
- DOCK2 | c.4801C>T p.R1601W | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1331646797, COSV56979171; called by muse, mutect2, varscan2
- DSEL | c.2791G>C p.G931R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59490776, COSV59493714; called by muse, mutect2, varscan2
- EDC4 | c.2578C>T p.R860* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs1265610875, COSV59302248; called by muse, mutect2, varscan2
- ELF4 | c.299A>T p.N100I | Missense Mutation (SNP) | VAF 86/141 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57454299; called by muse, mutect2, varscan2
- ELP3 | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99833940; called by muse, mutect2, varscan2
- ENAM | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV68536734; called by mutect2, varscan2
- EPHB1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67662422; called by muse, mutect2, varscan2
- FAM83H | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66354406; called by muse, mutect2, varscan2
- FAM91A1 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV58236025; called by muse, mutect2
- FAT4 | c.11308C>T p.R3770* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs761118468, COSV100628354; called by muse, mutect2, varscan2
- FCRL5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs763929627, COSV62513493; called by muse, mutect2, varscan2
- FGGY | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58045658; called by muse, mutect2
- GGPS1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as rs1034239262, COSV51397066; called by muse, mutect2, varscan2
- GOLT1B | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1365815047, COSV57554012; called by muse, mutect2, varscan2
- GRAMD1B | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs368784935; called by muse, mutect2, varscan2
- GRK2 | c.1439C>A p.A480D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100419646; called by muse, mutect2, varscan2
- HECW1 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771124413, COSV67835802; called by muse, varscan2
- IKZF3 | c.1010T>G p.V337G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV53105603; called by muse, mutect2, varscan2
- IL1RAP | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV50767457; called by muse, mutect2, varscan2
- ILRUN | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100927411; called by muse, mutect2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2
- LMO4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs771825798, COSV100983977, COSV65170301; called by muse, mutect2, varscan2
- LRRIQ1 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as rs374902495; called by muse, mutect2, varscan2
- MAGEE1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs374134344, COSV63911648; called by muse, mutect2, varscan2
- MYBPC3 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200399246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH3 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56868657; called by muse, mutect2, varscan2
- MYO3A | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1360882511, COSV56334269; called by muse, mutect2, varscan2
- NCAN | c.1936C>G p.H646D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53056160; called by muse, mutect2, varscan2
- NCKAP5 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100491473; called by muse, mutect2, varscan2
- NLRC3 | c.2081G>A p.R694K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV57094331; called by muse, mutect2, varscan2
- NLRP8 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as rs201462125; called by muse, mutect2, varscan2
- NMU | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as rs746842879, COSV51701367; called by muse, mutect2, varscan2
- NRIP1 | c.1952G>T p.S651I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV59655707, COSV59659439; called by muse, mutect2
- OBSCN | c.10169C>A p.P3390H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV52805177, COSV99476774; called by muse, mutect2
- OR10G2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs373027971; called by muse, varscan2
- OR2T11 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746166943, COSV58185125, COSV58186837; called by muse, mutect2, varscan2
- OR4C3 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV60586487, COSV60587472; called by muse, mutect2, varscan2
- PCDHA2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.024); catalogued as COSV65368199; called by muse, mutect2, varscan2
- PCDHGA6 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.433); catalogued as COSV99536412; called by muse, mutect2, varscan2
- PCDHGB7 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99536415; called by muse, mutect2, varscan2
- PDIA3 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | catalogued as COSV55857780; called by muse, mutect2
- PFKFB1 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 7/88 reads (8%) | PolyPhen benign (0.003); catalogued as COSV100895678; called by muse, mutect2
- PIPOX | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs763783220, COSV60143101; called by muse, mutect2, varscan2
- PROS1 | c.1020C>A p.Y340* | Nonsense Mutation (SNP) | VAF 64/193 reads (33%) | catalogued as BM1455323, COSV101260410, COSV101260492; called by muse, mutect2, varscan2
- PTPRM | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as rs200364748, COSV59848756, COSV59862738; called by muse, mutect2, varscan2
- RDH8 | c.989C>A p.P330Q (on ENST00000651512; = p.P310Q on NM_015725.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50676963; called by muse, mutect2, varscan2
- RFX5 | c.1680G>T p.L560F | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.347); catalogued as COSV100923867; called by muse, mutect2
- RYR2 | c.12152C>T p.A4051V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1326672128, COSV100769666; called by muse, mutect2, varscan2
- SLC16A5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150984642, COSV61675726; called by muse, mutect2, varscan2
- SLC17A7 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99676791; called by muse, mutect2, varscan2
- SLC1A7 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776329055, COSV100439411, COSV57016224; called by muse, mutect2, varscan2
- SLC6A20 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.093); catalogued as rs1478997348, COSV62070488, COSV62071925; called by muse, mutect2, varscan2
- SLITRK2 | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1283547485, COSV59427817; called by muse, mutect2, varscan2
- SMC4 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.605); catalogued as COSV100644014; called by muse, mutect2
- SMURF1 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs749123998, COSV62816601; called by muse, mutect2, varscan2
- SPHKAP | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60890386; called by muse, mutect2, varscan2
- SSH2 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52178781; called by muse, mutect2, varscan2
- TCERG1 | c.2126A>T p.Y709F | Missense Mutation (SNP) | VAF 147/265 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV57040544; called by muse, mutect2, varscan2
- THSD7A | c.3454C>A p.P1152T | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369978992; called by muse, mutect2
- TMEM94 | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774774722, COSV58598904; called by muse, mutect2, varscan2
- TRIM58 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV63571756; called by muse, mutect2, varscan2
- TTN | c.7057C>T p.P2353S (on ENST00000591111; = p.P2307S on NM_003319.4) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | PolyPhen possibly damaging (0.904); catalogued as rs753386940, COSV60257257; called by muse, mutect2, varscan2
- ULK2 | c.399A>T p.K133N | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100860762; called by muse, mutect2
- UNC45B | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs200725658, COSV52096769; called by muse, mutect2, varscan2
- XIRP2 | c.6081G>T p.K2027N (on ENST00000628543; = p.K2202N on NM_152381.6) | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54724748, COSV99746291; called by muse, mutect2, varscan2
- YWHAH | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV50708630; called by muse, mutect2, varscan2
- ZNF454 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV60769707; called by muse, mutect2
- ZNF565 | c.1493G>A p.R498H (on ENST00000355114; = p.R458H on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.904); catalogued as rs368382677; called by muse, mutect2, varscan2
- ZNF700 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54314679; called by muse, mutect2, varscan2
- ADGRL1 | c.1333G>C p.G445R (on ENST00000340736 / NM_001008701.3; = p.G440R on NM_014921.5) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); called by muse, mutect2
- GIMAP4 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- GNL3L | c.1364C>A p.P455Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- MAP3K4 | c.3595_3596del p.A1199Cfs*12 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by muse*, mutect2, varscan2*
- MRC1 | c.2484C>G p.C828W | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCMT1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF18 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- SLC16A6 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.355); called by muse, mutect2
- TTN | c.50294C>A p.P16765Q (on ENST00000591111; = p.P9341Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/100 reads (9%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- AC126283.2 | c.135A>G p.K45= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as CD111041, COSV101144368; called by muse, mutect2
- ADAMTS19 | c.2461A>C p.R821= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99177320; called by muse, mutect2
- ANKFY1 | c.2391C>T p.N797= (on ENST00000341657 / NM_001330063.2; = p.N798= on NM_016376.5) | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs375613181; called by muse, mutect2, varscan2
- APBB1IP | c.858T>G p.T286= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV66134976; called by muse, mutect2, varscan2
- ASXL3 | c.6051G>A p.P2017= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs779335040, COSV52475319; called by muse, mutect2, varscan2
- CDH9 | c.429G>A p.S143= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as rs748753503, COSV50274627, COSV99142992; called by muse, mutect2, varscan2
- CUBN | c.9339C>T p.C3113= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs758802682, COSV64711354; called by muse, mutect2, varscan2
- FBXL7 | c.990C>T p.S330= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV61642958; called by muse, mutect2
- GDAP2 | c.129A>G p.R43= | Silent (SNP) | VAF 59/171 reads (35%) | catalogued as rs374662005; called by muse, mutect2, varscan2
- GDI1 | c.309G>A p.K103= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs1057522885, COSV100870675; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN1 | c.297C>T p.N99= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1234541526, COSV59299548; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITPR2 | c.6816G>A p.A2272= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs766076424, COSV67274425; called by muse, mutect2, varscan2
- KCNG4 | c.882C>A p.P294= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100377022; called by muse, mutect2
- MACF1 | c.15267T>A p.S5089= (on ENST00000372915; = p.S3022= on NM_012090.5) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99243615; called by muse, mutect2
- MXRA5 | c.351G>T p.V117= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV54245617; called by muse, mutect2, varscan2
- MYH14 | c.5892G>A p.E1964= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV51827860; called by muse, varscan2
- MYH7 | c.4077C>T p.R1359= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs45523835, COSV62522390; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOM3 | c.1110C>T p.P370= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs761228879, COSV58399000; called by muse, mutect2, varscan2
- NEK10 | c.972C>A p.T324= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV58287920; called by muse, mutect2, varscan2
- PCDHB13 | c.1476G>A p.P492= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV53399644; called by muse, mutect2
- PLD1 | c.1545C>T p.A515= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs372404450; called by muse, mutect2, varscan2
- PPM1H | c.444G>A p.S148= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs1297859910, COSV57377828; called by muse, mutect2, varscan2
- PTCHD3 | c.462C>T p.T154= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs763146945, COSV71257196; called by muse, mutect2, varscan2
- SEL1L | c.2283C>T p.Y761= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as COSV60921865; called by muse, mutect2, varscan2
- SHISAL1 | c.456C>T p.P152= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs751318053, COSV66988553; called by muse, mutect2, varscan2
- SLC19A3 | c.1071C>T p.A357= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs957778131, COSV99295800; called by muse, mutect2, varscan2
- SLC4A1 | c.2403C>T p.S801= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs375505263; called by muse, mutect2, varscan2
- SPRY4 | c.732G>T p.V244= (on ENST00000434127 / NM_001127496.3; = p.V267= on NM_030964.4) | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV100702170; called by muse, mutect2, varscan2
- TAB3 | c.297A>C p.V99= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as COSV99916148; called by muse, mutect2, varscan2
- TMEM150B | c.519C>T p.H173= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs375954486, COSV58593433; called by muse, mutect2, varscan2
- TMEM45A | c.663C>T p.L221= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as COSV60255119; called by muse, mutect2, varscan2
- TNR | c.3708C>T p.A1236= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs755070959, COSV54903139; called by muse, mutect2, varscan2
- TUT1 | c.402G>T p.P134= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV53471473; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1914G>T p.L638= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV54299676; called by muse, mutect2, varscan2
- CD46 | c.*73_*93del | 3'UTR (DEL) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- NCL | c.898+62G>A | Intron (SNP) | VAF 21/211 reads (10%) | catalogued as COSV100502324; called by muse, mutect2, varscan2
- RBFOX1 | c.996-15725G>A | Intron (SNP) | VAF 36/90 reads (40%) | catalogued as rs550037838, COSV100299521, COSV60958818; called by muse, mutect2, varscan2
